Somatic mutation profile of tumor specimen MP2PRT-PASXXB-TMP1-A (aliquot MP2PRT-PASXXB-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASXXB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,880 days).
Specimen MP2PRT-PASXXB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d49756a-7afb-4aff-baff-582e85fa3991.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASXXB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASXXB-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a7e1deb-c80e-425f-b518-f2d48fc26767

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Frame Shift Ins 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2028C>G p.N676K | Missense Mutation (SNP) | VAF 84/459 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDH3B2 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 147/675 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs140738572; called by muse, mutect2, varscan2
- CFAP221 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763821756, COSV54655207; called by muse, varscan2
- NHLRC2 | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 91/483 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs142381455; called by muse, mutect2, varscan2
- OR1D2 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 105/682 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs780784044; called by muse, mutect2, varscan2
- PHACTR1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 101/557 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.587); catalogued as COSV100278622; called by muse, mutect2, varscan2
- PIEZO2 | c.3400G>A p.V1134I | Missense Mutation (SNP) | VAF 59/416 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs771172115; called by muse, mutect2, varscan2
- PTPN21 | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 175/1002 reads (17%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.04); catalogued as COSV100161550; called by muse, mutect2, varscan2
- RGS20 | c.526C>T p.R176W (on ENST00000297313 / NM_170587.4; = p.R29W on NM_003702.4) | Missense Mutation (SNP) | VAF 80/444 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1445147493; called by muse, varscan2
- SLC25A29 | c.677C>T p.P226L (on ENST00000359232 / NM_001039355.3; = p.P160L on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 159/877 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.148); catalogued as COSV63650581; called by muse, mutect2, varscan2
- UGT2B11 | c.287G>T p.R96I | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV71424567; called by muse, mutect2, varscan2
- UGT2B28 | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs775253593; called by muse, mutect2, varscan2
- ZNF770 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs561248623; called by muse, mutect2, varscan2
- LAMB1 | c.2305_2306insTCTC p.T769Ifs*7 | Frame Shift Ins (INS) | VAF 31/262 reads (12%) | called by mutect2, pindel, varscan2
- PCDHGB6 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 59/354 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- PODN | c.1974G>C p.E658D (on ENST00000395871; = p.E610D on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP4R3A | c.1365_1366insTTCA p.V456Ffs*3 (on ENST00000554943 / NM_001366432.1; = p.V443Ffs*3 on NM_001284280.1) | Frame Shift Ins (INS) | VAF 55/440 reads (13%) | called by mutect2, pindel, varscan2
- SALL3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 222/1150 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- SLC26A9 | c.2231dup p.T745Dfs*14 | Frame Shift Ins (INS) | VAF 67/457 reads (15%) | called by mutect2, pindel, varscan2
- TEP1 | c.3754G>A p.A1252T | Missense Mutation (SNP) | VAF 79/586 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- LRRTM1 | c.1215A>C p.T405= | Silent (SNP) | VAF 154/742 reads (21%) | called by muse, mutect2, varscan2
- PCSK1 | c.1824G>A p.T608= | Silent (SNP) | VAF 65/410 reads (16%) | catalogued as rs753294559; called by muse, mutect2, varscan2
- SALL3 | c.387G>A p.K129= | Silent (SNP) | VAF 222/1154 reads (19%) | called by muse, mutect2, varscan2
